Gene-level copy-number profile of specimen HCM-SANG-0287-C20-85A from HCMI case HCM-SANG-0287-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0287-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 59f4d91b-6fa1-462a-987a-cbada128fd31.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0287-C20-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/c88f041e-611d-4832-a7c5-65d3bbb70d09

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2; copy number 2: 1,101; copy number 3: 10; copy number 4: 20,957; copy number 5: 2,497; copy number 6: 31,780; copy number 7: 19; copy number 8: 1,461; copy number 9: 295; copy number 10: 765; copy number 11: 7; copy number 12: 20; copy number 30: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,811,359–143,825,837, 1 gene, copy number 30: AC239798.1.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
